Somatic mutation profile of tumor specimen TARGET-10-PAPIGD-09A (aliquot TARGET-10-PAPIGD-09A-01D) from TARGET case TARGET-10-PAPIGD, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.1 years (1,876 days).
Specimen TARGET-10-PAPIGD-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bfab84f9-09b1-41cc-99a4-47eb5855b065.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPIGD-10A (Blood Derived Normal), aliquot TARGET-10-PAPIGD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77b65ab4-b723-4653-8e78-c64f18baf842

The open-access MAF lists 29 somatic variants for this specimen: 20 protein-altering or splice-affecting, 2 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Intron 4, Nonsense Mutation 2, Silent 2, Frame Shift Ins 1, RNA 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.3521G>A p.G1174E | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs776576004, COSV67996312; called by muse, mutect2, varscan2
- DLX5 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.094); catalogued as rs758348857, COSV56032081; called by muse, mutect2, varscan2
- FGD1 | c.1867G>A p.V623M | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs754355805, COSV64309156; called by muse, mutect2, varscan2
- GABRA1 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1457242041, COSV50098975; called by muse, mutect2, varscan2
- GPR149 | c.1885G>T p.E629* | Nonsense Mutation (SNP) | VAF 23/61 reads (38%) | catalogued as COSV67669786; called by muse, mutect2, varscan2
- HMCN1 | c.6730C>T p.R2244* | Nonsense Mutation (SNP) | VAF 18/40 reads (45%) | catalogued as rs373249075, COSV54909354; called by muse, mutect2, varscan2
- MITF | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1478130504, COSV58881846; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MSL3 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1455131872, COSV56493209; called by muse, mutect2, varscan2
- NTM | c.367C>A p.P123T | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV100866773; called by muse, mutect2, varscan2
- PRDM5 | c.1231G>A p.A411T | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); catalogued as COSV53366595; called by muse, mutect2, varscan2
- SHB | c.1237G>A p.G413R | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780018157, COSV100891849; called by muse, mutect2, varscan2
- TMPRSS3 | c.1172C>T p.T391M | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs145766262, COSV52308871; ClinVar: uncertain significance; called by muse, mutect2
- DOCK2 | c.3999G>C p.M1333I | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.756); called by muse, varscan2
- DYRK4 | c.1237C>G p.Q413E | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- ETV6 | c.775dup p.R259Pfs*41 | Frame Shift Ins (INS) | VAF 23/69 reads (33%) | called by mutect2, pindel, varscan2
- GLUD2 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCYT1B | c.526G>T p.A176S | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- RRAGB | c.606T>G p.F202L (on ENST00000262850 / NM_016656.4; = p.F174L on NM_006064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- TMEM143 | c.163C>G p.R55G | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- TMEM178B | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCNT | c.5406G>C p.L1802= | Silent (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
- ZNF582 | c.117C>T p.Y39= | Silent (SNP) | VAF 13/28 reads (46%) | called by muse, mutect2, varscan2
- AR | c.-15C>T | 5'UTR (SNP) | VAF 5/54 reads (9%) | called by muse, mutect2
- FXYD2 | c.*6+139C>T | Intron (SNP) | VAF 8/16 reads (50%) | catalogued as rs967877014; called by muse, mutect2, varscan2
- ITGA5 | c.1463+84C>T | Intron (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- L3MBTL2 | c.262+21G>A | Intron (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- PARD6G | c.*98C>T | 3'UTR (SNP) | VAF 16/31 reads (52%) | catalogued as rs910284735; called by muse, mutect2, varscan2
- SERF2 | c.7+139C>A | Intron (SNP) | VAF 18/46 reads (39%) | called by muse, mutect2, varscan2
- YTHDF2P1 | n.111G>A | RNA (SNP) | VAF 9/15 reads (60%) | called by muse, mutect2, varscan2
